Somatic mutation profile of tumor specimen TCGA-55-8510-01A (aliquot TCGA-55-8510-01A-11D-2393-08) from TCGA case TCGA-55-8510, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.9 years (20,410 days).
Specimen TCGA-55-8510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f60cd9d-87fc-421e-aa75-7effba2fadef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8510-10A (Blood Derived Normal), aliquot TCGA-55-8510-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1a1d03d-5947-4489-81a5-ac3ddfc18fe0

The open-access MAF lists 337 somatic variants for this specimen: 251 protein-altering or splice-affecting, 79 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 79, Nonsense Mutation 15, Frame Shift Del 9, Splice Site 8, RNA 3, Splice Region 2, Intron 2, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs374211268; called by muse, mutect2
- ADGRG4 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54964082; called by muse, mutect2, varscan2
- ADGRG4 | c.6418C>G p.L2140V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs777240908, COSV99794588, COSV99796599; called by muse, mutect2, varscan2
- AEBP2 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99857551; called by muse, mutect2, varscan2
- AHNAK | c.10096A>T p.T3366S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.979); catalogued as COSV99945925; called by muse, mutect2, varscan2
- AL645922.1 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100190728; called by muse, mutect2
- AMOT | c.3005A>T p.Q1002L (on ENST00000371959 / NM_001113490.1; = p.Q593L on NM_133265.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV59060770; called by muse, mutect2
- ANK2 | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100000096; called by muse, mutect2, varscan2
- AOC1 | c.1931G>T p.W644L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710636; called by muse, mutect2, varscan2
- APC | c.3644G>T p.S1215I | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99965853; called by muse, mutect2, varscan2
- APOB | c.7962C>A p.N2654K | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV99264031; called by muse, mutect2, varscan2
- ARHGAP20 | c.3359G>A p.R1120K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52816593, COSV99503259; called by muse, mutect2, varscan2
- ARHGAP36 | c.893T>C p.F298S | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99357328; called by muse, mutect2, varscan2
- ASB1 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99223139; called by muse, mutect2, varscan2
- ASTN2 | c.1666C>G p.Q556E (on ENST00000313400 / NM_001365069.1; = p.Q505E on NM_014010.5) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100525207; called by muse, mutect2, varscan2
- ATG13 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100365535; called by muse, mutect2
- ATG5 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.208); catalogued as COSV100576400; called by muse, mutect2, varscan2
- ATP5F1E | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV99413930; called by muse, mutect2, varscan2
- BAG6 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV99276513; called by muse, mutect2, varscan2
- BPIFB4 | c.488C>A p.T163N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100971440; called by muse, mutect2, varscan2
- BRWD3 | c.875T>A p.I292N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100955723; called by muse, mutect2, varscan2
- CACNA1C | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100214272, COSV100215267; called by muse, mutect2, varscan2
- CACNA2D4 | c.2246A>T p.E749V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99765193; called by muse, mutect2, varscan2
- CADM2 | c.1225G>T p.D409Y (on ENST00000407528 / NM_001167674.2; = p.D411Y on NM_153184.4) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101053184; called by muse, mutect2, varscan2
- CARD11 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101210433, COSV67800265; called by muse, mutect2, varscan2
- CASP5 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs768531296, COSV99507240; called by muse, mutect2
- CATSPERD | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101062424, COSV67536988; called by muse, mutect2
- CBX4 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs745582907, COSV99490239; called by muse, mutect2, varscan2
- CCDC91 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100081409; called by muse, mutect2, varscan2
- CDH10 | c.1842G>C p.L614F | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1393876469, COSV100050337, COSV52581148; called by muse, mutect2, varscan2
- CDH8 | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100179910, COSV100184518, COSV54905279; called by muse, mutect2, varscan2
- CERK | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as COSV53450802; called by muse, mutect2
- CFC1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99383438; called by muse, mutect2
- CLCA2 | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991400; called by muse, mutect2, varscan2
- CNTNAP2 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV100663501; called by muse, mutect2, varscan2
- CNTNAP4 | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100269710; called by muse, varscan2
- COG5 | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.714); catalogued as COSV99771511; called by muse, mutect2, varscan2
- COL1A1 | c.2848G>T p.G950W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070689, COSV56806952, COSV99866549; called by muse, mutect2, varscan2
- COL25A1 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211256; called by muse, mutect2
- COPG1 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100135415; called by muse, mutect2, varscan2
- CPS1 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99242345; called by muse, mutect2, varscan2
- CR1 | c.275G>T p.W92L | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100887418; called by muse, mutect2, varscan2
- CSMD3 | c.2864C>A p.P955Q (on ENST00000297405 / NM_001363185.1; = p.P851Q on NM_052900.3) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99826966; called by muse, mutect2, varscan2
- DDR2 | c.52T>A p.L18M | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV100906231; called by muse, mutect2, varscan2
- DGKB | c.1757A>T p.Y586F | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99337004; called by muse, mutect2
- DIS3L | c.1928G>T p.R643L (on ENST00000319212 / NM_001143688.3; = p.R560L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054910; called by muse, mutect2, varscan2
- DNAH9 | c.3984C>A p.N1328K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99304522; called by muse, mutect2
- DOK6 | c.886C>G p.R296G | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.391); catalogued as COSV101234304; called by muse, mutect2, varscan2
- DPH1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99559446; called by muse, mutect2, varscan2
- DPH1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99559447; called by muse, mutect2, varscan2
- DVL2 | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99138361; called by muse, mutect2, varscan2
- DXO | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV100514580; called by muse, mutect2, varscan2
- DYRK1B | c.1399A>T p.I467F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV100546455; called by muse, mutect2, varscan2
- E2F4 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100103603; called by muse, mutect2, varscan2
- EDA | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs1284952129, COSV65770846; called by muse, mutect2, varscan2
- EPHA5 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56643710, COSV99897943; called by muse, mutect2
- ERBB4 | c.1360A>T p.S454C | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99617872; called by muse, mutect2, varscan2
- ERI3 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100952068; called by muse, mutect2, varscan2
- ERICH3 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV100443589; called by muse, mutect2, varscan2
- F13B | c.985+1G>T p.X329_splice | Splice Site (SNP) | VAF 34/153 reads (22%) | catalogued as COSV100803208; called by muse, mutect2, varscan2
- FAAH2 | c.743-1G>T p.X248_splice | Splice Site (SNP) | VAF 27/130 reads (21%) | catalogued as COSV100887175; called by muse, mutect2, varscan2
- FAM110B | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366785580, COSV100826039; called by muse, mutect2
- FAM71B | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100261898, COSV57231962; called by muse, mutect2, varscan2
- FAM83C | c.1585C>A p.P529T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV100981523; called by muse, mutect2, varscan2
- FAT2 | c.8172C>A p.Y2724* | Nonsense Mutation (SNP) | VAF 28/121 reads (23%) | catalogued as COSV99941905; called by muse, mutect2, varscan2
- FILIP1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780969364, COSV99384050; called by muse, mutect2, varscan2
- FLNA | c.4820C>A p.A1607D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100774343; called by muse, mutect2, varscan2
- FNIP1 | c.455+1G>T p.X152_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100330291; called by muse, varscan2
- FRMD7 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV100048731; called by muse, mutect2, varscan2
- FRMPD4 | c.3251C>A p.T1084N | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV101042293; called by muse, mutect2, varscan2
- FRY | c.6220A>G p.M2074V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100968856; called by muse, mutect2
- FSHR | c.153G>C p.L51= | Splice Region (SNP) | VAF 21/131 reads (16%) | catalogued as COSV58620432, COSV58625002; called by muse, mutect2, varscan2
- GABRA4 | c.663A>T p.L221F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99973638; called by muse, mutect2, varscan2
- GABRB1 | c.914C>A p.A305E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99780466; called by muse, mutect2
- GFRA1 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as rs1050293557, COSV100815513, COSV62601826; called by muse, mutect2, varscan2
- GJA9 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100668044; called by muse, mutect2, varscan2
- GRIK3 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100901471, COSV66135314; called by muse, mutect2, varscan2
- GRIN2B | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101662936; called by muse, mutect2, varscan2
- GTF3C1 | c.4590G>T p.M1530I | Missense Mutation (SNP) | VAF 119/341 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100649038; called by muse, mutect2, varscan2
- GTF3C1 | c.3779G>T p.R1260L | Missense Mutation (SNP) | VAF 82/423 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100649039, COSV62239618; called by muse, mutect2, varscan2
- H2AC12 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV100804583; called by muse, mutect2, varscan2
- HCN1 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100298940; called by muse, mutect2, varscan2
- HELQ | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99787454; called by muse, mutect2, varscan2
- HGF | c.1640G>T p.W547L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV55958800; called by muse, mutect2, varscan2
- HOXA5 | c.647T>A p.F216Y | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV99762125; called by muse, mutect2, varscan2
- HTR1E | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99044539; called by muse, mutect2, varscan2
- HTR3C | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100570508; called by muse, mutect2, varscan2
- HYDIN | c.11623C>A p.L3875M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV101124932; called by muse, mutect2, varscan2
- IGSF10 | c.4709G>T p.W1570L | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99176824; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1722T>A p.D574E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV100145557; called by muse, mutect2, varscan2
- INKA1 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as COSV100323536; called by muse, mutect2
- INPP4B | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99523277; called by muse, mutect2, varscan2
- ITPRID1 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100085822; called by muse, mutect2, varscan2
- ITSN1 | c.2060G>T p.S687I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV101180448; called by muse, mutect2, varscan2
- KAT2A | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99288061; called by muse, mutect2, varscan2
- KCNT2 | c.2252C>G p.P751R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54111137, COSV99651947; called by muse, mutect2, varscan2
- KEAP1 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99407412, COSV99407659; called by muse, mutect2, varscan2
- KLB | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99961980; called by muse, mutect2, varscan2
- KLRF1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs763517073, COSV99684308; called by muse, mutect2, varscan2
- KRT14 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs267607397, CM103089, COSV99390913; ClinVar: not provided; called by muse, mutect2, varscan2
- KTN1 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs770189058, COSV101255018; called by muse, mutect2
- L1CAM | c.1787A>T p.E596V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as COSV100648903; called by muse, mutect2, varscan2
- LIFR | c.2318T>C p.M773T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99663452; called by muse, mutect2, varscan2
- LILRA4 | c.1426A>T p.R476W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99392948; called by muse, mutect2, varscan2
- LILRB1 | c.204G>T p.W68C (on ENST00000427581; = p.W32C on NM_006669.6) | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100207002; called by muse, mutect2, varscan2
- LILRB1 | c.796G>T p.V266L (on ENST00000427581; = p.V230L on NM_006669.6) | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100207004; called by muse, mutect2, varscan2
- LIN28A | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99575228; called by muse, mutect2, varscan2
- LRFN5 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as COSV53281742; called by muse, mutect2, varscan2
- LRP1B | c.5759-1G>T p.X1920_splice | Splice Site (SNP) | VAF 14/104 reads (13%) | catalogued as COSV101253618; called by muse, mutect2, varscan2
- LRRC32 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476726; called by muse, mutect2, varscan2
- LUM | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99898824; called by muse, mutect2, varscan2
- LYPD4 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100419332, COSV58027960; called by muse, mutect2, varscan2
- LYST | c.11287G>T p.G3763C | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); catalogued as COSV101088432; called by muse, mutect2, varscan2
- MAPK3 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99531306; called by muse, mutect2, varscan2
- MAPKBP1 | c.3081T>A p.D1027E (on ENST00000456763 / NM_001128608.2; = p.D1021E on NM_014994.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99529015; called by muse, mutect2, varscan2
- MDC1 | c.2975G>T p.G992V | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs982149395, COSV100902650; called by muse, mutect2, varscan2
- MSH3 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs963584392, COSV99432447; called by muse, mutect2
- MTNR1B | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV57069861; called by muse, mutect2, varscan2
- MUC16 | c.1336G>T p.G446* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV101198439, COSV67470021; called by muse, mutect2, varscan2
- MYH14 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99221962; called by muse, mutect2
- MYO16 | c.5199G>C p.Q1733H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV100696050; called by muse, mutect2, varscan2
- MYO18B | c.6793G>T p.G2265C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100122810, COSV59143541; called by muse, mutect2, varscan2
- NAALAD2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100428119; called by muse, mutect2, varscan2
- NAALADL2 | c.2120T>A p.M707K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101495204; called by muse, mutect2, varscan2
- NAP1L2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100999187; called by muse, varscan2
- NAV3 | c.1369A>G p.S457G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV99887644; called by muse, mutect2, varscan2
- NEB | c.9263G>T p.S3088I | Missense Mutation (SNP) | VAF 56/710 reads (8%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.98); catalogued as COSV99416209; called by muse, mutect2
- NID1 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV99937086; called by muse, mutect2
- NKAP | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV101004191; called by muse, mutect2
- NMUR2 | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99676670; called by muse, mutect2, varscan2
- NOBOX | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV56197639, COSV99779234; called by muse, mutect2, varscan2
- NVL | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99893781; called by muse, mutect2, varscan2
- NYNRIN | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV101230520; called by muse, mutect2, varscan2
- OBSCN | c.16968G>C p.W5656C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs770857552, COSV52806947, COSV99473832, COSV99474054; called by muse, mutect2, varscan2
- ONECUT1 | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100009059; called by muse, mutect2, varscan2
- OPHN1 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100830244; called by muse, mutect2, varscan2
- OPN1SW | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs62479596, COSV99975512; called by muse, mutect2, varscan2
- OR10G2 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101606935; called by muse, mutect2, varscan2
- OR11H6 | c.508G>C p.G170R | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100209724, COSV59644698; called by muse, mutect2, varscan2
- OR11H6 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100209726; called by muse, mutect2, varscan2
- OR2G2 | c.728C>G p.T243S | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100189611; called by muse, mutect2, varscan2
- OR2T4 | c.465C>A p.Y155* | Nonsense Mutation (SNP) | VAF 65/356 reads (18%) | catalogued as COSV100822408, COSV63543926; called by muse, mutect2
- OR4C11 | c.545T>A p.L182* | Nonsense Mutation (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100155241, COSV100155273; called by muse, mutect2
- OR5D13 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100686752; called by muse, mutect2, varscan2
- OR8K5 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100537160; called by muse, mutect2, varscan2
- PAGE3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.971); catalogued as rs771711717, COSV100891972; called by muse, mutect2, varscan2
- PBDC1 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100972788; called by muse, mutect2
- PCARE | c.3107C>A p.P1036H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100527364; called by muse, mutect2, varscan2
- PCDH7 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.997); catalogued as COSV100687657; called by muse, mutect2, varscan2
- PCDHGA11 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99532549; called by muse, mutect2, varscan2
- PCDHGA5 | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV53952766, COSV99532542; called by muse, mutect2, varscan2
- PCDHGA7 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV99532547; called by muse, mutect2, varscan2
- PCLO | c.15327G>T p.K5109N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428224; called by muse, mutect2, varscan2
- PCSK2 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99358845; called by muse, mutect2, varscan2
- PDE1C | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.43); catalogued as rs1458207638, COSV58524660; called by muse, mutect2, varscan2
- PDE7B | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs754776704, COSV100367407; called by muse, mutect2, varscan2
- PGK2 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV100505359; called by muse, mutect2, varscan2
- PHB2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99780981; called by muse, mutect2, varscan2
- PHF20L1 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.719); catalogued as COSV99620379, COSV99620535; called by muse, mutect2, varscan2
- PITPNM3 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99338013; called by muse, mutect2, varscan2
- PITX3 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1463122881, COSV100892752; called by muse, mutect2
- PKP4 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | catalogued as COSV101080358; called by muse, mutect2, varscan2
- PLEKHA4 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV99612169; called by muse, mutect2, varscan2
- PLEKHG4B | c.1996G>C p.D666H (on ENST00000283426; = p.D1022H on NM_052909.5) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99359892; called by muse, mutect2
- PLEKHH2 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99174385; called by muse, mutect2, varscan2
- PRKCI | c.1602G>T p.Q534H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99855673; called by muse, mutect2, varscan2
- PRKG1 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV100907159, COSV64777880; called by muse, mutect2, varscan2
- PRSS36 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99191233; called by muse, mutect2, varscan2
- PSG7 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 99/323 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs532113687, COSV68447492; called by muse, mutect2, varscan2
- PSG8 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100126021; called by muse, mutect2, varscan2
- PTCHD4 | c.761T>G p.M254R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100260275; called by muse, mutect2, varscan2
- PTPRH | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99670765; called by muse, mutect2, varscan2
- RABL6 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.201); catalogued as rs1431988361, COSV100272944; called by muse, mutect2, varscan2
- RBM26 | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV99935878; called by muse, mutect2, varscan2
- RELN | c.3820C>A p.P1274T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV100632700; called by muse, mutect2, varscan2
- RGS22 | c.2362G>T p.V788L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371240281, COSV100693027; called by muse, mutect2
- RGS7 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV100465196, COSV58547794; called by muse, mutect2, varscan2
- RTN4RL2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100625398; called by muse, mutect2
- RYR2 | c.12078G>T p.L4026F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV100768507; called by muse, mutect2, varscan2
- SAMHD1 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53432789; called by muse, mutect2, varscan2
- SEMA3A | c.2126T>C p.L709P | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545594; called by muse, mutect2
- SERPINB3 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 45/210 reads (21%) | catalogued as COSV99379508, COSV99379631; called by muse, mutect2, varscan2
- SERPING1 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99557857; called by muse, mutect2, varscan2
- SETD1A | c.4496A>G p.Y1499C | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1247389436, COSV99352538; called by muse, mutect2
- SETD1A | c.4498T>A p.Y1500N | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352541; called by muse, mutect2
- SIGLEC1 | c.4204G>A p.V1402I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV99163395; called by muse, mutect2
- SIPA1L1 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100665216; called by muse, mutect2, varscan2
- SLC18A1 | c.1464+1G>T p.X488_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99368343; called by muse, mutect2, varscan2
- SLC22A6 | c.534C>A p.C178* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs753679674, COSV100842802; called by muse, mutect2, varscan2
- SLC30A6 | c.1145G>T p.S382I | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV99249408; called by muse, mutect2, varscan2
- SLC5A12 | c.1516T>A p.Y506N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101237597; called by muse, mutect2
- SLC8A1 | c.2896G>T p.A966S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.194); catalogued as COSV100244875; called by muse, mutect2, varscan2
- SLITRK4 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100567189; called by muse, mutect2, varscan2
- SMR3B | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as rs763561228, COSV100513330; called by muse, mutect2, varscan2
- SPRR2B | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV100482248, COSV100482291; called by muse, mutect2, varscan2
- SPRY1 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100201776; called by muse, mutect2, varscan2
- SSTR4 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54798322, COSV99658418; called by muse, mutect2
- STARD10 | c.429C>G p.Y143* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100600410; called by muse, mutect2, varscan2
- STIM1 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330557; called by muse, mutect2, varscan2
- STK17A | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as COSV100082028; called by muse, mutect2
- STX11 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100845467; called by muse, mutect2, varscan2
- SYMPK | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99841442; called by muse, mutect2, varscan2
- TAS2R41 | c.355T>A p.F119I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101281474; called by muse, mutect2, varscan2
- TBCEL | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as COSV99411961; called by muse, mutect2, varscan2
- TBX19 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100892334, COSV63197754; called by muse, mutect2, varscan2
- TCEAL2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV100216239; called by muse, mutect2, varscan2
- TCHHL1 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV100916503; called by muse, mutect2, varscan2
- TEKT3 | c.664-2A>T p.X222_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100106853; called by mutect2, varscan2
- THOC2 | c.1360C>A p.R454S | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55554072; called by muse, mutect2
- TMEM132E | c.2507A>T p.Q836L (on ENST00000321639; = p.Q926L on NM_001304438.2) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100395992, COSV100396822; called by muse, mutect2, varscan2
- TMPRSS11A | c.1151G>T p.W384L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100602577; called by muse, mutect2, varscan2
- TRPV2 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV100641135, COSV100641298; called by muse, mutect2, varscan2
- TRRAP | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100722100, COSV62843942; called by muse, mutect2, varscan2
- UGT2A1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV99683913; called by muse, mutect2, varscan2
- UGT2A3 | c.790T>A p.F264I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99279658; called by muse, mutect2, varscan2
- UHRF1 | c.1888G>A p.E630K (on ENST00000612630 / NM_001290050.1; = p.E643K on NM_013282.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV99503343; called by muse, mutect2
- UPF3B | c.697A>T p.R233W | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99352001; called by muse, mutect2, varscan2
- VPS50 | c.2401G>T p.V801L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100004564; called by muse, mutect2, varscan2
- WSCD1 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1190889176, COSV100496420, COSV100496764; called by muse, mutect2, varscan2
- WWTR1 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100640789; called by muse, mutect2, varscan2
- ZC3H13 | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs763604474, COSV54449272, COSV99667632; called by muse, mutect2, varscan2
- ZC3HC1 | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100315637; called by muse, mutect2, varscan2
- ZCCHC14 | c.1778G>T p.R593L (on ENST00000268616; = p.R730L on NM_015144.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs961896964, COSV99233388; called by muse, mutect2, varscan2
- ZDHHC9 | c.328+1G>T p.X110_splice | Splice Site (SNP) | VAF 24/238 reads (10%) | catalogued as COSV100852131; called by muse, mutect2, varscan2
- ZGPAT | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100203098; called by muse, mutect2, varscan2
- ZMIZ2 | c.1573A>G p.I525V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs771553576, COSV99536629; called by muse, mutect2, varscan2
- ZNF831 | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV64043430; called by muse, mutect2, varscan2
- ZNF831 | c.854T>C p.M285T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64041698; called by muse, mutect2, varscan2
- ZPLD1 | c.1087C>A p.P363T (on ENST00000466937 / NM_001329788.1; = p.P379T on NM_175056.2) | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1401000554, COSV100082968; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2287dup p.W763Lfs*4 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- ARFGAP2 | c.480del p.Q160Hfs*49 | Frame Shift Del (DEL) | VAF 61/409 reads (15%) | called by mutect2, pindel, varscan2
- C11orf16 | c.1205del p.G402Efs*23 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- C1QTNF12 | c.314del p.P105Qfs*8 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- CDH16 | c.286-2dup p.X96_splice | Splice Site (INS) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- CXorf58 | c.786G>C p.R262S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- HMCN1 | c.13143_13144del p.Q4382Vfs*9 | Frame Shift Del (DEL) | VAF 21/143 reads (15%) | called by mutect2, pindel, varscan2
- HUWE1 | c.13072del p.H4358Tfs*105 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- IDO2 | c.1142del p.G381Afs*8 (on ENST00000389060; = p.G394Afs*8 on NM_194294.2) | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by mutect2, varscan2
- IGKV2-30 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2
- IGKV2D-24 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- KIAA1109 | c.11626A>G p.I3876V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2
- MAMDC2 | c.401dup p.N134Kfs*26 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- MUC5B | c.5804del p.P1935Lfs*5 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- OR8J3 | c.668del p.L223Cfs*4 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- PHF8 | c.1026del p.K342Nfs*17 (on ENST00000357988 / NM_001184896.1; = p.K306Nfs*17 on NM_015107.3) | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel*
- SEMA3G | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC7A4 | c.772A>T p.S258C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2
- SYNRG | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- VIL1 | c.150T>A p.A50= | Splice Region (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2
- ZNF707 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.608); called by muse, mutect2
- ADAD1 | c.1479C>A p.I493= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs1402807506, COSV56647243, COSV99635176; called by muse, mutect2, varscan2
- ALS2 | c.4380C>T p.S1460= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99968872; called by muse, mutect2, varscan2
- AMER3 | c.1773G>T p.G591= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100366083; called by muse, mutect2, varscan2
- APC | c.2682G>T p.V894= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99965851; called by muse, mutect2, varscan2
- ARHGAP6 | c.1443C>A p.L481= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV100272412; called by muse, mutect2, varscan2
- ARMC5 | c.957C>T p.G319= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99192348; called by muse, mutect2, varscan2
- ARSH | c.1098G>A p.P366= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs373570475, COSV66962780; called by mutect2, varscan2
- C1QC | c.558C>A p.G186= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV101009408; called by muse, mutect2, varscan2
- CAPN15 | c.2202G>T p.R734= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as COSV99562221; called by muse, mutect2, varscan2
- CKB | c.606G>A p.L202= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV62379404; called by muse, mutect2, varscan2
- COL6A3 | c.4644G>T p.L1548= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as COSV55098508; called by muse, mutect2
- CPSF3 | c.495C>T p.F165= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99432533; called by muse, mutect2, varscan2
- CRLF2 | c.531C>A p.A177= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV101053567; called by muse, mutect2, varscan2
- CYLC1 | c.432C>G p.S144= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100254165; called by muse, mutect2, varscan2
- DBH | c.762C>T p.T254= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV99707944; called by muse, mutect2, varscan2
- DIS3L | c.1929A>T p.R643= (on ENST00000319212 / NM_001143688.3; = p.R560= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as COSV100054915; called by muse, mutect2, varscan2
- DYNC1I1 | c.396G>T p.V132= | Silent (SNP) | VAF 70/421 reads (17%) | catalogued as COSV100267768, COSV61465815; called by muse, mutect2, varscan2
- ENPEP | c.856C>T p.L286= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV54453392, COSV99487187; called by muse, mutect2, varscan2
- FLG2 | c.6162C>A p.A2054= | Silent (SNP) | VAF 178/1005 reads (18%) | catalogued as COSV101165631, COSV101166321; called by muse, mutect2, varscan2
- FMR1 | c.1452C>A p.R484= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as COSV54423175, COSV99503026; called by muse, mutect2, varscan2
- FRMPD4 | c.2886C>A p.G962= | Silent (SNP) | VAF 43/189 reads (23%) | catalogued as COSV101042291; called by muse, mutect2, varscan2
- GAL3ST4 | c.387C>A p.P129= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99444400; called by muse, mutect2
- GJA10 | c.1464C>A p.I488= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV101005292; called by muse, mutect2, varscan2
- GPR88 | c.876C>A p.V292= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100159443; called by muse, mutect2, varscan2
- HERC2 | c.13377C>T p.L4459= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs748097233, COSV99871472; called by muse, mutect2, varscan2
- HLX | c.1122T>G p.A374= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100854470; called by muse, mutect2, varscan2
- KRBA1 | c.2016C>T p.R672= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99752195; called by muse, mutect2
- LAMB4 | c.912G>C p.P304= | Silent (SNP) | VAF 44/273 reads (16%) | catalogued as COSV52718283, COSV99223102; called by muse, mutect2, varscan2
- LAMP5 | c.198T>C p.F66= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV99855464; called by muse, mutect2, varscan2
- LHX9 | c.843C>T p.T281= | Silent (SNP) | VAF 83/242 reads (34%) | catalogued as COSV100435655; called by muse, mutect2, varscan2
- LINGO1 | c.366G>T p.R122= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100796295; called by muse, mutect2
- LRP1 | c.10065C>T p.T3355= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs370463475; called by muse, mutect2, varscan2
- LRPPRC | c.879G>T p.V293= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99580042; called by muse, mutect2, varscan2
- MAST4 | c.7674G>T p.G2558= (on ENST00000403625 / NM_001164664.2; = p.G2369= on NM_015183.3) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99843143; called by muse, mutect2, varscan2
- MATN1 | c.1065G>T p.G355= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs1169620506, COSV101056194; called by muse, mutect2
- MBL2 | c.330A>C p.S110= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100906270; called by muse, mutect2
- MPP1 | c.1278C>T p.Y426= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs1275391587, COSV101053854; called by muse, mutect2, varscan2
- MUC5B | c.12981C>G p.P4327= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as rs757200827, COSV101500069; called by muse, mutect2, varscan2
- MYH14 | c.2514G>T p.R838= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99221967; called by muse, mutect2
- MYH2 | c.4968C>A p.L1656= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV99819428; called by muse, mutect2, varscan2
- MYRIP | c.1881G>A p.Q627= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100218457, COSV56875606; called by muse, mutect2, varscan2
- N6AMT1 | c.180T>G p.S60= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100374883; called by muse, mutect2, varscan2
- NAV3 | c.1368C>A p.L456= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV99887640; called by muse, mutect2, varscan2
- NAV3 | c.6577C>A p.R2193= (on ENST00000397909 / NM_001024383.2; = p.R2171= on NM_014903.6) | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV57061219, COSV99887647; called by muse, mutect2, varscan2
- NEURL4 | c.2574G>T p.S858= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100222740, COSV100222994; called by muse, mutect2, varscan2
- NPAP1 | c.1185C>G p.T395= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100274879; called by muse, mutect2, varscan2
- NRXN2 | c.738C>T p.H246= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99632782; called by muse, mutect2, varscan2
- OR13A1 | c.165G>T p.G55= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100980982; called by muse, mutect2
- OR14I1 | c.237C>A p.S79= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100700435; called by muse, mutect2, varscan2
- OR1M1 | c.147C>T p.I49= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV101447544; called by muse, mutect2
- OR7E24 | c.162G>A p.L54= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV101509640; called by muse, mutect2, varscan2
- OR8J1 | c.925C>T p.L309= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs372843205; called by muse, mutect2, varscan2
- OSBPL6 | c.1950A>T p.P650= | Silent (SNP) | VAF 87/434 reads (20%) | catalogued as COSV99506802; called by muse, mutect2, varscan2
- PCDH15 | c.4296G>A p.V1432= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs1564552874, COSV100216579; called by muse, mutect2, varscan2
- PCDHB8 | c.1971C>A p.A657= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV99176090; called by muse, varscan2
- PGD | c.243G>T p.V81= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99581208; called by muse, mutect2, varscan2
- PHB2 | c.48C>T p.P16= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1555151938, COSV99780982; called by muse, mutect2, varscan2
- PLPPR4 | c.339T>A p.I113= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV100927036; called by muse, mutect2
- PROKR2 | c.796C>A p.R266= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99449940; called by muse, mutect2, varscan2
- RHOT2 | c.1440A>T p.T480= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99552819; called by muse, mutect2, varscan2
- RIPK2 | c.387C>T p.A129= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as COSV99609717; called by muse, mutect2, varscan2
- RYR2 | c.2289C>A p.A763= | Silent (SNP) | VAF 75/338 reads (22%) | catalogued as COSV100768506; called by muse, mutect2, varscan2
- SASS6 | c.60G>A p.E20= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as COSV99790648; called by muse, mutect2
- SIGLEC1 | c.1551G>T p.P517= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52467132, COSV99163397; called by muse, mutect2, varscan2
- SLAMF7 | c.960C>G p.L320= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100833216; called by muse, mutect2, varscan2
- SLC25A47 | c.471C>A p.P157= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100690044; called by muse, mutect2, varscan2
- SLC9A4 | c.426C>A p.G142= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs575529823, COSV54828670, COSV54837751; called by muse, mutect2, varscan2
- SUGP2 | c.1467G>A p.L489= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs746526863, COSV100431541; called by muse, mutect2, varscan2
- TBR1 | c.1200C>T p.T400= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1225351764, COSV101271417; called by muse, mutect2, varscan2
- TCHHL1 | c.1947C>T p.P649= | Silent (SNP) | VAF 38/217 reads (18%) | catalogued as COSV64287379; called by muse, mutect2, varscan2
- TGFBR2 | c.123C>T p.N41= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55447073, COSV99846648; called by muse, mutect2, varscan2
- TOX2 | c.747G>A p.K249= (on ENST00000358131 / NM_001098798.2; = p.K198= on NM_032883.3) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100363430; called by muse, mutect2
- TRAM1 | c.756G>T p.L252= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs776288293, COSV99140726; called by muse, mutect2, varscan2
- TRIOBP | c.6585G>A p.V2195= (on ENST00000644935 / NM_001039141.3; = p.V482= on NM_007032.5) | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100730669; called by muse, mutect2, varscan2
- TSHZ3 | c.1011A>T p.T337= | Silent (SNP) | VAF 76/213 reads (36%) | catalogued as COSV99550820; called by muse, mutect2, varscan2
- TSPYL6 | c.504C>A p.G168= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV100336335, COSV57818293; called by muse, mutect2, varscan2
- UBE2D2 | c.246C>A p.G82= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99551303; called by muse, mutect2, varscan2
- UNC5A | c.966C>A p.V322= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99994247; called by muse, mutect2, varscan2
- ZC3H3 | c.1587T>C p.T529= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs762809561, COSV99367487; called by muse, mutect2
- AL353804.4 | chrX:73826022 C>A | 5'Flank (SNP) | VAF 45/236 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503850 C>T | 5'Flank (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.153del | RNA (DEL) | VAF 23/115 reads (20%) | called by mutect2, pindel, varscan2
- MIR329-2 | n.59C>T | RNA (SNP) | VAF 16/162 reads (10%) | catalogued as rs1416165952; called by muse, mutect2, varscan2
- MTHFD1L | c.2847+4699C>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- MTHFD1L | c.2847+4700C>T | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.34G>T | RNA (SNP) | VAF 44/336 reads (13%) | called by muse, mutect2, varscan2
